Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A9U5, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A9U5-01A (Primary Tumor).

(MM/DD/YYYY)

ICD O-3
Carcinoma, squamous cell NOS
8070/3
Site: Cervix NOS
C53.9
9/3/14

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

Uterine cervix biopsy:

Poorly differentiated squamous cell carcinoma, invasive, with necrosis areas.
Angiolymphatic and perineural infiltrations not observed.

Source: NCI Genomic Data Commons file bd891b83-1463-47cf-abaa-9371cc170055 (TCGA-VS-A9U5.4DCCBB92-3E31-4B62-8F8E-00264488ADD0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).